Gene-level copy-number profile of tumor specimen TCGA-3B-A9HY-01A from TCGA case TCGA-3B-A9HY, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-3B-A9HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e1fa1873-2679-4815-acf6-f74dfe35cc47.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/347cdddc-b8ee-40b7-b53f-319a9b3d879d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,465; copy number 2: 44,851; copy number 3: 961; copy number 4: 106; copy number 5: 415; copy number 10: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HY-01A-11D-A38Y-01): tumor purity 0.85, ploidy 1.83, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 435 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:34,692,290–36,814,792, 18 genes, copy number 10: AC073218.1, AC012593.2, AC012593.1, RN7SL602P, AC019064.1, SMIM7P1, AC013442.1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1, RPL21P36, CRIM1-DT, CRIM1, AC007378.1, FEZ2, AC007363.1, VIT.
- chr2:36,839,922–36,867,495, 2 genes, copy number 10: AC007382.1, RNU6-577P.
- chr17:10,729,777–10,880,895, 1 gene, copy number 5 (within-gene range 1–5): AC015908.7.
- chr17:10,792,059–21,574,517, 414 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,078. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
